Gene-level copy-number profile of specimen HCM-SANG-1081-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-1081-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-1081-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eafd65f9-6789-4471-a023-67de88218111.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1081-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/9c110c06-87f6-4b22-89ff-749f135f490a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,506; copy number 2: 27,058; copy number 3: 23,481; copy number 4: 4,482; copy number 5: 1,354; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,356 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:71,032,670–71,093,193, 2 genes, copy number 6: GTF2H2, OCLNP1.
- chr8:56,160,909–145,066,685, 1,345 genes, copy number 5 (broad region; genes not listed).
- chr11:2,129,112–2,173,138, 9 genes, copy number 5: IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686.

Autosomal genes at a single copy (total copy number 1): 2,506. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
